Gene-level copy-number profile of tumor specimen TCGA-44-8117-01A from TCGA case TCGA-44-8117, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.4 years (19,855 days).
Specimen TCGA-44-8117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b0446a3f-fc44-4e47-945c-e516eb1af863.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-8117-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab6b3032-d853-4149-938f-979ed076d931

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 2,638; copy number 2: 21,897; copy number 3: 19,060; copy number 4: 11,684; copy number 5: 1,327; copy number 6: 2,472; copy number 7: 427; copy number 8: 230; copy number 9: 33; copy number 13: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-8117-01A-11D-2237-01): tumor purity 0.66, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:23,403,848–24,090,821, 11 genes: AC100756.3, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P, PWRN4.
- chr15:24,162,754–24,240,192, 3 genes: PWRN2, AC087463.1, AC087463.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,474 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,778,087–186,681,446, 1,429 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–55,173,177, 787 genes, copy number 5–8 (broad region; genes not listed).
- chr5:56,770,799–57,320,020, 14 genes, copy number 5: AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1.
- chr5:60,699,729–62,777,263, 33 genes, copy number 5: AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057, ZSWIM6, AC122718.2, AC122718.1, RPL3P6, C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1, AC008877.1, RN7SKP157, KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3, AC114982.1, RPL35AP14, LRRC70, ISCA1P1.
- chr10:67,334,123–73,358,859, 161 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:823,634–2,318,204, 73 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:13,276,652–16,739,591, 48 genes, copy number 5 (within-gene range 2–5): ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P.
- chr11:21,169,748–27,220,113, 50 genes, copy number 5 (within-gene range 4–5): AC090857.1, AC090857.2, AC099730.1, RNA5SP337, AC130307.1, ANO5, AC116534.1, AC107882.1, AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, AC021698.1, ANO3-AS1, AC079064.1, MUC15, SLC5A12, FIBIN, BBOX1, BBOX1-AS1.
- chr11:54,591,480–61,020,377, 314 genes, copy number 5 (broad region; genes not listed).
- chr20:36,233,851–64,313,132, 690 genes, copy number 5–13 (broad region; genes not listed).
- chr22:20,859,007–39,532,761, 797 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr22:41,922,032–44,312,951, 78 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,331. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
